Somatic mutation profile of tumor specimen MBCProject_1334_T2_WES (aliquot MBCProject_1334_T2_WES_1) from CMI case MBCProject_1334, project CMI-MBC: Count Me In (CMI): The Metastatic Breast Cancer (MBC) Project. Sex at birth: female; Primary diagnosis: Infiltrating duct and lobular carcinoma; Tissue or organ of origin: Breast, NOS; Age at diagnosis: 61.4 years (22,433 days).
Specimen MBCProject_1334_T2_WES: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Breast; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) cb5faf3d-f986-49ed-8c98-1a28c38ce811.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MBCProject_1334_SALIVA (Saliva), aliquot MBCProject_1334_SALIVA_1; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/bac363cf-be21-484c-b879-ab85055e480e

The open-access MAF lists 135 somatic variants for this specimen: 88 protein-altering or splice-affecting, 34 silent, 13 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 78, Silent 34, Intron 10, Nonsense Mutation 4, Frame Shift Del 3, Splice Region 1, In Frame Ins 1, Splice Site 1, 5'UTR 1, 3'UTR 1, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- DAXX | c.1353_1355dup p.E457dup | In Frame Ins (INS) | VAF 39/246 reads (16%) | hotspot (GDC flag); catalogued as rs762240849; called by mutect2, varscan2
- PIK3CA | c.3140A>G p.H1047R | Missense Mutation (SNP) | VAF 34/127 reads (27%) | hotspot (GDC flag); SIFT tolerated (0.11); PolyPhen benign (0.085); catalogued as rs121913279, CM153086, COSV55873195, COSV55873401, COSV55888015; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- TP53 | c.403T>C p.C135R | Missense Mutation (SNP) | VAF 49/185 reads (26%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1057519975, COSV52674321, COSV52706302, COSV52827707; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- AATK | c.865C>T p.Q289* (on ENST00000326724 / NM_001080395.3; = p.Q186* on NM_004920.2) | Nonsense Mutation (SNP) | VAF 5/86 reads (6%) | catalogued as rs1290826380; called by muse, mutect2
- ANKRD18A | c.2170G>C p.E724Q | Missense Mutation (SNP) | VAF 18/204 reads (9%) | SIFT tolerated (0.44); PolyPhen probably damaging (0.932); catalogued as rs1180925024, COSV101294918, COSV101294929; called by muse, mutect2
- ARFGEF3 | c.1318C>T p.L440F | Missense Mutation (SNP) | VAF 10/169 reads (6%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.994); catalogued as rs1426064069; called by muse, mutect2
- ATN1 | c.3235C>G p.L1079V | Missense Mutation (SNP) | VAF 58/590 reads (10%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.994); catalogued as rs1555144539; called by muse, mutect2
- ATP10B | c.4144C>A p.P1382T | Missense Mutation (SNP) | VAF 13/308 reads (4%) | SIFT tolerated (0.14); PolyPhen benign (0.04); catalogued as COSV59167238; called by muse, mutect2
- ATP7A | c.4382G>A p.R1461K | Missense Mutation (SNP) | VAF 20/284 reads (7%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.792); catalogued as COSV58455515; called by muse, mutect2
- BFSP2 | c.376G>C p.E126Q | Missense Mutation (SNP) | VAF 28/385 reads (7%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as rs1052451744; called by muse, mutect2
- BICC1 | c.2452G>A p.D818N | Missense Mutation (SNP) | VAF 32/358 reads (9%) | SIFT deleterious (0); PolyPhen benign (0.054); catalogued as rs773272305, COSV99570485; called by muse, mutect2
- CADM1 | c.785C>T p.A262V | Missense Mutation (SNP) | VAF 37/370 reads (10%) | SIFT tolerated (0.23); PolyPhen benign (0.166); catalogued as rs1216125604, COSV59010956; called by muse, mutect2
- CCDC73 | c.2008A>G p.K670E | Missense Mutation (SNP) | VAF 57/156 reads (37%) | SIFT tolerated (0.33); PolyPhen benign (0.006); catalogued as COSV58799392; called by muse, mutect2, varscan2
- DPYSL4 | c.768G>A p.M256I | Missense Mutation (SNP) | VAF 10/125 reads (8%) | SIFT deleterious (0.02); PolyPhen benign (0.444); catalogued as rs767477122; called by muse, mutect2
- EP300 | c.1592C>T p.S531L | Missense Mutation (SNP) | VAF 32/358 reads (9%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.616); catalogued as COSV99610236; called by muse, mutect2
- EXOSC10 | c.2183A>C p.Q728P (on ENST00000376936 / NM_001001998.3; = p.Q703P on NM_002685.4) | Missense Mutation (SNP) | VAF 12/150 reads (8%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.644); catalogued as rs1171695597; called by muse, mutect2
- FOXP4 | c.1712del p.N571Mfs*22 (on ENST00000307972 / NM_001012426.1; = p.N558Mfs*22 on NM_138457.3) | Frame Shift Del (DEL) | VAF 38/155 reads (25%) | catalogued as COSV100332538; called by mutect2, pindel, varscan2
- GALT | c.98G>T p.R33L | Missense Mutation (SNP) | VAF 85/452 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as CM065206, CM151305; called by muse, mutect2, varscan2
- GCN1 | c.7536G>A p.M2512I | Missense Mutation (SNP) | VAF 17/244 reads (7%) | SIFT tolerated (0.59); PolyPhen benign (0); catalogued as rs766837866; called by muse, mutect2
- GDPD5 | c.839G>A p.R280Q | Missense Mutation (SNP) | VAF 18/256 reads (7%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.962); catalogued as rs956450520, COSV61126668; called by muse, mutect2
- HBP1 | c.970C>A p.P324T | Missense Mutation (SNP) | VAF 11/185 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as rs865904902; called by muse, mutect2
- KCNA1 | c.268G>A p.D90N | Missense Mutation (SNP) | VAF 16/490 reads (3%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.689); catalogued as COSV101230302, COSV66838782; called by muse, mutect2
- LDB3 | c.914C>T p.A305V | Missense Mutation (SNP) | VAF 33/386 reads (9%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.98); catalogued as rs544084461, COSV53950265; called by muse, mutect2
- MAST4 | c.1469C>T p.P490L (on ENST00000403625 / NM_001164664.2; = p.P301L on NM_015183.3) | Missense Mutation (SNP) | VAF 45/218 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs764589271; called by muse, mutect2, varscan2
- MOB1A | c.616G>T p.E206* | Nonsense Mutation (SNP) | VAF 12/342 reads (4%) | catalogued as COSV68517297; called by muse, mutect2
- MPP6 | c.596G>A p.G199E | Missense Mutation (SNP) | VAF 12/127 reads (9%) | SIFT tolerated (0.35); PolyPhen possibly damaging (0.533); catalogued as COSV56041559, COSV56043569; called by muse, mutect2
- MST1 | c.579G>C p.Q193H | Missense Mutation (SNP) | VAF 15/228 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV56531992; called by muse, mutect2
- MUC4 | c.1043C>A p.T348K | Missense Mutation (SNP) | VAF 8/110 reads (7%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.413); catalogued as COSV62149573; called by muse, mutect2
- PALD1 | c.242C>T p.T81M | Missense Mutation (SNP) | VAF 64/238 reads (27%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.686); catalogued as rs143276983; called by muse, mutect2, varscan2
- PFKM | c.13G>A p.E5K | Missense Mutation (SNP) | VAF 18/250 reads (7%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.111); catalogued as rs190392934; called by muse, mutect2
- SERPINE2 | c.1076-4G>A | Splice Region (SNP) | VAF 26/214 reads (12%) | catalogued as rs567218200; called by muse, mutect2, varscan2
- SLC6A15 | c.523C>G p.Q175E | Missense Mutation (SNP) | VAF 16/373 reads (4%) | SIFT tolerated (0.23); PolyPhen benign (0.04); catalogued as COSV57027260; called by muse, mutect2
- AAK1 | c.151G>T p.V51L | Missense Mutation (SNP) | VAF 58/662 reads (9%) | SIFT tolerated (0.15); PolyPhen benign (0.329); called by muse, mutect2
- ADCY8 | c.502C>T p.R168C | Missense Mutation (SNP) | VAF 93/200 reads (47%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.446); called by muse, mutect2, varscan2
- ANKRD53 | c.1124A>G p.Y375C | Missense Mutation (SNP) | VAF 61/379 reads (16%) | SIFT tolerated (0.09); PolyPhen benign (0.211); called by muse, mutect2, varscan2
- ARHGEF19 | c.964G>A p.E322K | Missense Mutation (SNP) | VAF 9/66 reads (14%) | SIFT tolerated (0.15); PolyPhen benign (0.023); called by muse, mutect2
- BCL2L12 | c.82C>G p.Q28E | Missense Mutation (SNP) | VAF 10/142 reads (7%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.14); called by muse, mutect2
- CD163L1 | c.1727C>T p.S576L | Missense Mutation (SNP) | VAF 5/40 reads (13%) | SIFT tolerated (0.69); PolyPhen benign (0.255); called by muse, mutect2
- CD5L | c.50T>A p.F17Y | Missense Mutation (SNP) | VAF 17/307 reads (6%) | SIFT deleterious (0.01); PolyPhen benign (0.135); called by muse, mutect2
- CD99L2 | c.12G>A p.W4* | Nonsense Mutation (SNP) | VAF 9/75 reads (12%) | called by muse, mutect2
- CIT | c.5187G>T p.E1729D | Missense Mutation (SNP) | VAF 12/143 reads (8%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.989); called by muse, mutect2
- CLASP1 | c.1681G>A p.E561K | Missense Mutation (SNP) | VAF 10/131 reads (8%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.991); called by muse, mutect2
- CLRN1 | c.121A>G p.K41E | Missense Mutation (SNP) | VAF 24/436 reads (6%) | SIFT deleterious (0.01); PolyPhen benign (0.192); called by muse, mutect2
- CYP4V2 | c.1398C>A p.N466K | Missense Mutation (SNP) | VAF 16/272 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- DAB2 | c.1192T>A p.F398I | Missense Mutation (SNP) | VAF 14/434 reads (3%) | SIFT deleterious (0); PolyPhen possibly damaging (0.558); called by muse, mutect2
- DOCK2 | c.515T>A p.I172N | Missense Mutation (SNP) | VAF 12/214 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); called by muse, mutect2
- GASK1A | c.652G>C p.E218Q | Missense Mutation (SNP) | VAF 24/116 reads (21%) | SIFT tolerated (0.16); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- HBQ1 | c.416C>A p.S139Y | Missense Mutation (SNP) | VAF 51/146 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.904); called by muse, mutect2, varscan2
- HDHD3 | c.389G>A p.R130K | Missense Mutation (SNP) | VAF 8/152 reads (5%) | SIFT tolerated (0.86); PolyPhen benign (0); called by muse, mutect2
- HLA-F | c.415T>G p.Y139D | Missense Mutation (SNP) | VAF 16/364 reads (4%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.992); called by muse, mutect2
- IGHD | c.187T>A p.Y63N | Missense Mutation (SNP) | VAF 44/244 reads (18%) | SIFT tolerated (0.3); PolyPhen benign (0.184); called by muse, mutect2, varscan2
- KAT6B | c.4440C>G p.D1480E | Missense Mutation (SNP) | VAF 27/720 reads (4%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0); called by muse, mutect2
- KCTD13 | c.773G>A p.R258Q | Missense Mutation (SNP) | VAF 3/40 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); called by muse, mutect2
- KIAA1755 | c.448C>G p.L150V | Missense Mutation (SNP) | VAF 9/165 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2
- KIDINS220 | c.3743C>G p.A1248G | Missense Mutation (SNP) | VAF 10/184 reads (5%) | SIFT tolerated (0.31); PolyPhen benign (0.081); called by muse, mutect2
- KLRG2 | c.215C>T p.S72L | Missense Mutation (SNP) | VAF 7/32 reads (22%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- MAMDC4 | c.2292C>G p.H764Q (on ENST00000445819; = p.H685Q on NM_206920.3) | Missense Mutation (SNP) | VAF 18/138 reads (13%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- MGAM2 | c.4172G>T p.S1391I | Missense Mutation (SNP) | VAF 13/99 reads (13%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.487); called by muse, mutect2, varscan2
- NBPF9 | c.120G>C p.E40D | Missense Mutation (SNP) | VAF 33/477 reads (7%) | SIFT deleterious (0); PolyPhen benign (0.316); called by muse, mutect2
- NMRK1 | c.431A>G p.D144G | Missense Mutation (SNP) | VAF 20/185 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- OR4A5 | c.430G>C p.V144L | Missense Mutation (SNP) | VAF 10/234 reads (4%) | SIFT tolerated, low confidence (0.58); PolyPhen benign (0.02); called by muse, mutect2
- OR6M1 | c.700G>T p.A234S | Missense Mutation (SNP) | VAF 10/64 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.951); called by muse, mutect2, varscan2
- PCDHGC5 | c.1830G>T p.L610F | Missense Mutation (SNP) | VAF 24/212 reads (11%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.973); called by muse, mutect2, varscan2
- PNLDC1 | c.320A>G p.Y107C | Missense Mutation (SNP) | VAF 13/165 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2
- PPP4R3C | c.856A>C p.N286H | Missense Mutation (SNP) | VAF 6/88 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.983); called by muse, mutect2
- PPWD1 | c.1411G>A p.E471K | Missense Mutation (SNP) | VAF 8/200 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- PTPRZ1 | c.1175G>C p.C392S | Missense Mutation (SNP) | VAF 17/215 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- RPS6KA6 | c.1144C>T p.H382Y | Missense Mutation (SNP) | VAF 24/223 reads (11%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.808); called by muse, mutect2, varscan2
- SBF2 | c.2953G>C p.D985H | Missense Mutation (SNP) | VAF 30/426 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- SBF2 | c.2606A>C p.Q869P | Missense Mutation (SNP) | VAF 22/289 reads (8%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.696); called by muse, mutect2
- SETBP1 | c.1186G>C p.D396H | Missense Mutation (SNP) | VAF 23/137 reads (17%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.74); called by muse, mutect2, varscan2
- SIRT5 | c.760G>C p.V254L | Missense Mutation (SNP) | VAF 9/284 reads (3%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.964); called by muse, mutect2
- SLC52A1 | c.1022G>T p.G341V | Missense Mutation (SNP) | VAF 19/92 reads (21%) | SIFT tolerated (0.24); PolyPhen benign (0.133); called by muse, mutect2, varscan2
- SMC3 | c.3476-1G>A p.X1159_splice | Splice Site (SNP) | VAF 20/284 reads (7%) | called by muse, mutect2
- SPDEF | c.883_896del p.K295Hfs*44 | Frame Shift Del (DEL) | VAF 26/134 reads (19%) | called by mutect2, pindel, varscan2
- SUPT16H | c.1684G>A p.E562K | Missense Mutation (SNP) | VAF 15/141 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- TH | c.121C>A p.L41I | Missense Mutation (SNP) | VAF 7/112 reads (6%) | SIFT tolerated, low confidence (0.6); PolyPhen benign (0.011); called by muse, mutect2
- THEGL | c.677del p.N226Tfs*28 | Frame Shift Del (DEL) | VAF 17/102 reads (17%) | called by mutect2, pindel, varscan2
- TKT | c.562G>A p.G188S | Missense Mutation (SNP) | VAF 37/143 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.935); called by muse, mutect2, varscan2
- TNRC18 | c.5204C>G p.S1735* | Nonsense Mutation (SNP) | VAF 4/49 reads (8%) | called by muse, mutect2
- TRAPPC5 | c.185G>A p.G62D | Missense Mutation (SNP) | VAF 12/57 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- TTLL3 | c.959G>C p.G320A | Missense Mutation (SNP) | VAF 5/67 reads (7%) | SIFT tolerated (0.15); PolyPhen benign (0.011); called by muse, mutect2
- TUBGCP5 | c.1363G>A p.E455K | Missense Mutation (SNP) | VAF 16/144 reads (11%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.718); called by muse, mutect2
- USH2A | c.8466G>C p.Q2822H | Missense Mutation (SNP) | VAF 7/143 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.905); called by muse, mutect2
- USP35 | c.92A>T p.Q31L | Missense Mutation (SNP) | VAF 45/124 reads (36%) | SIFT tolerated (0.07); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- XK | c.181G>T p.D61Y | Missense Mutation (SNP) | VAF 17/265 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); called by muse, mutect2
- ZBTB2 | c.124C>A p.L42I | Missense Mutation (SNP) | VAF 11/304 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2
- ZNF808 | c.951T>G p.C317W | Missense Mutation (SNP) | VAF 10/155 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- ABHD16B | c.363C>T p.R121= | Silent (SNP) | VAF 10/39 reads (26%) | catalogued as rs1388141787; called by muse, mutect2, varscan2
- ACTN4 | c.2145G>A p.Q715= | Silent (SNP) | VAF 12/223 reads (5%) | called by muse, mutect2
- BTN3A1 | c.1539G>C p.A513= | Silent (SNP) | VAF 5/44 reads (11%) | called by muse, mutect2
- CCDC106 | c.777C>G p.L259= | Silent (SNP) | VAF 61/183 reads (33%) | called by muse, mutect2, varscan2
- CDH26 | c.228T>A p.G76= | Silent (SNP) | VAF 12/138 reads (9%) | called by muse, mutect2
- CYP2B6 | c.945C>G p.L315= | Silent (SNP) | VAF 16/189 reads (8%) | called by muse, mutect2
- DEAF1 | c.672G>T p.R224= | Silent (SNP) | VAF 22/316 reads (7%) | called by muse, mutect2
- EIF2AK3 | c.2079A>T p.P693= | Silent (SNP) | VAF 38/466 reads (8%) | called by muse, mutect2
- EPHA4 | c.2736T>C p.A912= | Silent (SNP) | VAF 32/328 reads (10%) | called by muse, mutect2
- FAM50A | c.666C>A p.T222= | Silent (SNP) | VAF 10/253 reads (4%) | catalogued as COSV50131116; called by muse, mutect2
- H1-7 | c.450G>A p.A150= | Silent (SNP) | VAF 24/203 reads (12%) | called by muse, mutect2, varscan2
- HAUS5 | c.1725G>A p.E575= | Silent (SNP) | VAF 50/187 reads (27%) | catalogued as COSV52548023; called by muse, mutect2, varscan2
- HK1 | c.36A>G p.A12= | Silent (SNP) | VAF 16/464 reads (3%) | called by muse, mutect2
- IGFALS | c.564G>A p.A188= | Silent (SNP) | VAF 52/143 reads (36%) | catalogued as rs746027443; called by muse, mutect2, varscan2
- KRT72 | c.1113C>T p.I371= | Silent (SNP) | VAF 14/126 reads (11%) | catalogued as rs776455684, COSV53376957; called by muse, mutect2, varscan2
- MCF2 | c.2664C>T p.I888= | Silent (SNP) | VAF 10/165 reads (6%) | called by muse, mutect2
- MCOLN3 | c.1236C>T p.V412= | Silent (SNP) | VAF 16/106 reads (15%) | called by muse, mutect2, varscan2
- MXRA5 | c.8385G>A p.L2795= | Silent (SNP) | VAF 26/300 reads (9%) | called by muse, mutect2
- PCDHA11 | c.1713C>T p.S571= | Silent (SNP) | VAF 44/450 reads (10%) | catalogued as COSV56539229; called by muse, mutect2
- PCDHA4 | c.822T>C p.N274= | Silent (SNP) | VAF 11/156 reads (7%) | called by muse, mutect2
- PCDHGB6 | c.258G>A p.V86= | Silent (SNP) | VAF 22/356 reads (6%) | called by muse, mutect2
- PDE8B | c.141C>T p.T47= | Silent (SNP) | VAF 10/134 reads (7%) | catalogued as rs893629710; called by muse, mutect2
- PDGFRB | c.1986G>C p.L662= | Silent (SNP) | VAF 16/192 reads (8%) | called by muse, mutect2
- ROBO2 | c.114C>T p.S38= | Silent (SNP) | VAF 3/37 reads (8%) | catalogued as rs1258028092; called by muse, mutect2
- SEC24C | c.411T>G p.A137= | Silent (SNP) | VAF 11/135 reads (8%) | called by muse, mutect2
- SETX | c.354G>A p.L118= | Silent (SNP) | VAF 26/313 reads (8%) | called by muse, mutect2
- SLC39A7 | c.1332A>G p.S444= | Silent (SNP) | VAF 38/514 reads (7%) | catalogued as rs749753724; called by muse, mutect2
- TBC1D8 | c.546C>T p.I182= | Silent (SNP) | VAF 8/124 reads (6%) | called by muse, mutect2
- TENM4 | c.4536C>A p.G1512= | Silent (SNP) | VAF 15/150 reads (10%) | called by muse, mutect2
- UBQLN3 | c.321C>T p.V107= | Silent (SNP) | VAF 12/103 reads (12%) | called by muse, mutect2, varscan2
- VRTN | c.1926G>A p.V642= | Silent (SNP) | VAF 10/76 reads (13%) | called by muse, mutect2, varscan2
- XPO6 | c.309T>G p.P103= | Silent (SNP) | VAF 42/560 reads (8%) | called by muse, mutect2
- ZNF440 | c.346C>T p.L116= | Silent (SNP) | VAF 66/211 reads (31%) | called by muse, mutect2, varscan2
- ZNF692 | c.702C>G p.T234= | Silent (SNP) | VAF 260/414 reads (63%) | called by muse, mutect2, varscan2
- ANO4 | c.-108C>T | 5'UTR (SNP) | VAF 29/235 reads (12%) | catalogued as rs759282849, COSV100151364; called by muse, mutect2, varscan2
- ANXA2 | c.-116-2743del | Intron (DEL) | VAF 22/184 reads (12%) | called by mutect2, pindel, varscan2
- ATP8B4 | c.1758+1003dup | Intron (INS) | VAF 30/176 reads (17%) | catalogued as rs1410062220; called by mutect2, varscan2
- CBFA2T3 | c.893+9G>C | Intron (SNP) | VAF 12/71 reads (17%) | catalogued as rs752068990; called by muse, mutect2, varscan2
- CFL2 | c.*2166A>G | 3'UTR (SNP) | VAF 49/169 reads (29%) | called by muse, mutect2, varscan2
- FAM136A | c.87+199T>C | Intron (SNP) | VAF 6/67 reads (9%) | called by muse, mutect2
- GRM4 | c.520-10009C>G | Intron (SNP) | VAF 12/164 reads (7%) | called by muse, mutect2
- KRT16P2 | n.627G>A | RNA (SNP) | VAF 11/82 reads (13%) | catalogued as rs568121759; called by mutect2, varscan2
- OFD1 | c.2758-30G>A | Intron (SNP) | VAF 49/296 reads (17%) | called by muse, mutect2, varscan2
- PFKFB3 | c.1515+1839A>T | Intron (SNP) | VAF 16/356 reads (4%) | called by muse, mutect2
- PLXNC1 | c.2882-254T>C | Intron (SNP) | VAF 14/277 reads (5%) | called by muse, mutect2
- VPS13B | c.4820+15653G>A | Intron (SNP) | VAF 31/204 reads (15%) | called by muse, mutect2, varscan2
- ZNF268 | c.33+2703C>T | Intron (SNP) | VAF 7/71 reads (10%) | catalogued as rs1156846731; called by muse, mutect2
